Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB3B, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB3B-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD O-3
Sarcoma, synovial monophase
fibrous
90413
Site: Leg NOS C49.2
703/10/14

....

Clinical Diagnosis & History:

[REDACTED] with previously diagnosed history of synovial sarcoma left ankle.
FNA 10 days prior to resection.

Specimens Submitted:

1: SP: Left below the knee amputation leg

DIAGNOSIS:

- 1) LEFT LEG, BEOW THE KNEE AMPUTATION:
- HIGH GRADE MONOPHASIC SYNOVIAL SARCOMA, INVOLVING SUBCUTANEOUS TISSUE, SKELETAL MUSCLE, ENCASING LARGE NERVE TRUNKS, AND INVADING INTO THE TALUS BONE.
- TUMOR IS PREDOMINANTLY VIABLE.
- TUMOR SIZE: 10.5 X 8.2 X 7.2 CM.
- BONE AND SOFT TISSUE MARGINS NEGATIVE FOR TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) Received fresh labeled "left below knee amputation" is a distal leg and left foot. The leg measures 32.1 cm in length with a circumference of 33 cm. The tibia has a diameter of 2.9 cm and the fibula 1.3 cm. There is a bulging mass protruding from the medial aspect of the left ankle that measures 10.5 x 8.2 x 7.2 cm and involved the posterior, medial, and anterior aspects of the tibia. The mass is white to pink/red with areas of hemorrhage and involves portions of the talus bone measuring 3.7 x 2.2 cm in area. It is located 11.5 cm from the nearest soft tissue margin. TPS, photos, and representative sections were taken.

Summary:

Skinm-skin margin

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2

Ves-vessels at margin
Tlat-tumor at lateral aspect near FNA site
Tant-anterior tumor
Tpost-posterior tumor
T-tumor random

Summary of Sections:

Part 1: SP: Left below the knee amputation leg

Block	Sect.	Site	PCs
1	A		1
1	B		1
1	C		1
1	D		1
1	E		1
1	F		1
1	fib		1
1	G		1
1	skinm		1
1	T		1
2	Tant		2
2	tibia		2
2	Tlat		2
2	Tpost		2
1	ves		1

** End of Report **

Criteria	hw 1/24/14	Yes	No
HIPAA Discrepancy	Reference		✓

Source: NCI Genomic Data Commons file 93946ab4-1ce8-4f46-aa73-ef41427120f8 (TCGA-DX-AB3B.3CD48C1D-47A6-4FEF-A575-9742B0D8E371.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).